Somatic mutation profile of tumor specimen TCGA-DD-AADY-01A (aliquot TCGA-DD-AADY-01A-11D-A40R-10) from TCGA case TCGA-DD-AADY, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 55.4 years (20,233 days).
Specimen TCGA-DD-AADY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5d4b9ff-8d8c-4f3f-ae30-b6af758a8be9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AADY-10A (Blood Derived Normal), aliquot TCGA-DD-AADY-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4fd650e2-8ebc-4da4-ae26-142ae2c66398

The open-access MAF lists 47 somatic variants for this specimen: 39 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 7, Frame Shift Ins 3, Nonsense Mutation 3, Splice Site 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL2A1 | c.2659C>T p.R887* | Nonsense Mutation (SNP) | VAF 79/173 reads (46%) | catalogued as rs1399676515, CM062564, COSV100477261; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABTB1 | c.1066G>A p.A356T (on ENST00000232744 / NM_172027.3; = p.A214T on NM_032548.3) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs376513209; called by mutect2, varscan2
- ATP2B3 | c.2783A>T p.N928I | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99685535; called by muse, mutect2, varscan2
- BAX | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.65); catalogued as rs369660551; called by muse, mutect2, varscan2
- BTAF1 | c.215A>T p.N72I | Missense Mutation (SNP) | VAF 77/89 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV56432906, COSV99795705; called by muse, mutect2, varscan2
- C10orf90 | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 59/79 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs762197645, COSV52949865; called by muse, mutect2, varscan2
- CELF1 | c.342G>T p.M114I | Missense Mutation (SNP) | VAF 76/177 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV100137169; called by muse, mutect2, varscan2
- DCHS1 | c.9592C>T p.R3198C | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs779065285, COSV54997901; called by muse, mutect2, varscan2
- EIF2D | c.793G>T p.D265Y | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99662991; called by muse, mutect2, varscan2
- GCC2 | c.2548A>T p.I850L | Missense Mutation (SNP) | VAF 168/377 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100565606; called by muse, mutect2, varscan2
- GHSR | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 29/991 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV53838301; called by muse, mutect2
- GIGYF1 | c.2804A>G p.Y935C | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1469202420, COSV99309863; called by muse, mutect2, varscan2
- HERC1 | c.60G>T p.W20C | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV101496833; called by muse, mutect2, varscan2
- KCNA6 | c.1448G>C p.G483A | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.007); catalogued as COSV99768893; called by muse, mutect2, varscan2
- LAMB3 | c.1627G>T p.G543C | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV100620489; called by muse, mutect2, varscan2
- MYH2 | c.556A>C p.T186P | Missense Mutation (SNP) | VAF 73/90 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as COSV99820754; called by muse, mutect2, varscan2
- NCOR1 | c.1198C>T p.L400F | Missense Mutation (SNP) | VAF 101/132 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51995111, COSV99251620; called by muse, mutect2, varscan2
- PCDHAC1 | c.2666C>T p.P889L | Missense Mutation (SNP) | VAF 84/183 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV53843388, COSV99155114; called by muse, mutect2, varscan2
- PLEC | c.3574G>C p.E1192Q (on ENST00000322810 / NM_201380.4; = p.E1082Q on NM_000445.5) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as rs1554710424, COSV100517980; called by muse, mutect2, varscan2
- PPP2R1B | c.1276G>C p.D426H | Missense Mutation (SNP) | VAF 56/70 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1555048181, COSV100232348; called by muse, mutect2, varscan2
- RAI1 | c.3950A>G p.K1317R | Missense Mutation (SNP) | VAF 32/39 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99884811; called by muse, mutect2, varscan2
- RHOBTB1 | c.1644G>T p.L548F | Missense Mutation (SNP) | VAF 72/87 reads (83%) | SIFT tolerated (0.93); PolyPhen benign (0.06); catalogued as COSV100558646; called by muse, mutect2, varscan2
- SEC23IP | c.1598A>T p.N533I | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100957049; called by muse, mutect2, varscan2
- SIM2 | c.644A>G p.Q215R | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV99293539; called by muse, mutect2, varscan2
- SLCO1B1 | c.1039T>G p.L347V | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as COSV99918954; called by muse, mutect2, varscan2
- SPATS2L | c.1184A>G p.N395S | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs760101340, COSV62349417; called by muse, mutect2, varscan2
- STMN4 | c.560C>A p.A187D (on ENST00000265770 / NM_001283054.2; = p.A214D on NM_030795.4) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.477); catalogued as COSV99741103; called by muse, mutect2, varscan2
- SYNE2 | c.19762G>T p.E6588* | Nonsense Mutation (SNP) | VAF 71/155 reads (46%) | catalogued as COSV100648360, COSV59972085; called by muse, mutect2, varscan2
- TEX37 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 127/258 reads (49%) | catalogued as rs753124892, COSV100304666; called by muse, mutect2, varscan2
- TTC13 | c.2310-1G>A p.X770_splice | Splice Site (SNP) | VAF 11/155 reads (7%) | catalogued as rs769986902, COSV100792994; called by muse, mutect2
- TTN | c.79787T>C p.I26596T (on ENST00000591111; = p.I19172T on NM_003319.4) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | PolyPhen benign (0.011); catalogued as COSV100625962; called by muse, mutect2, varscan2
- TUT1 | c.2110G>A p.A704T | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV99545536; called by muse, mutect2, varscan2
- VPS13C | c.8285G>A p.S2762N (on ENST00000644861 / NM_020821.3; = p.S2719N on NM_017684.5) | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV99829820; called by muse, mutect2
- ZDBF2 | c.2875G>A p.D959N | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV100985385; called by muse, mutect2, varscan2
- ZNF175 | c.1187G>T p.C396F | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51796201; called by muse, mutect2, varscan2
- CEP350 | c.5174dup p.H1726Tfs*9 | Frame Shift Ins (INS) | VAF 59/270 reads (22%) | called by mutect2, varscan2
- NCOR1 | c.1573dup p.T525Nfs*11 | Frame Shift Ins (INS) | VAF 79/130 reads (61%) | called by mutect2, pindel, varscan2
- PBRM1 | c.1248dup p.Y417Ifs*3 | Frame Shift Ins (INS) | VAF 49/83 reads (59%) | called by mutect2, pindel, varscan2
- SPTAN1 | c.5328_5342+2del p.X1776_splice | Splice Site (DEL) | VAF 19/70 reads (27%) | called by mutect2, pindel, varscan2
- AFTPH | c.1377C>G p.A459= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as COSV99481125; called by muse, mutect2, varscan2
- CUX2 | c.6C>T p.A2= | Silent (SNP) | VAF 46/54 reads (85%) | catalogued as rs1452102872, COSV99920508; called by muse, mutect2, varscan2
- MAGEA1 | c.660G>C p.V220= | Silent (SNP) | VAF 78/184 reads (42%) | catalogued as COSV100756674; called by muse, mutect2, varscan2
- NLGN4X | c.261G>C p.R87= | Silent (SNP) | VAF 69/167 reads (41%) | catalogued as COSV52019878, COSV99323482; called by muse, mutect2, varscan2
- POFUT1 | c.291G>A p.Q97= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as COSV100998403; called by muse, mutect2, varscan2
- PXDN | c.3933G>A p.V1311= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs1233812644, COSV53247159, COSV99414632; called by muse, mutect2, varscan2
- UBL4A | c.171G>A p.S57= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as rs1557212770, COSV54837293; called by muse, mutect2, varscan2
- MACF1 | c.15832-8636C>T | Intron (SNP) | VAF 7/42 reads (17%) | catalogued as rs1158641177, COSV57110919; called by muse, mutect2, varscan2
